Surgical pathology report (de-identified scan), TCGA case TCGA-WC-A883, project TCGA-UVM (Uveal Melanoma), tissue source site MD Anderson, specimen TCGA-WC-A883-01A (Primary Tumor).

[page 1 of 2]
Accession:

Specimen Date/Time:

ICD-0-3

Melanoma, epithelioid & spindle cell
mixed 8770/3

Site: Choroid 069.3

9/11/14

DIAGNOSIS

(A) RIGHT EYE, FNA SAMPLE FOR SEND OUT TESTING ONLY.

(B) RIGHT GLOBE:

(1-30%)

(61-90%)

CHOROIDAL MELANOMA, MIXED EPITHELIOID AND SPINDLED, 18 MM BASE.

EXTRAOCULAR EXTENSION PRESENT.

TUMOR INVADES SCLERA AND CANAL OF SCHLEMM, EXTENDING TO SUBCONJUNCTIVAL SURFACE.

Optic nerve negative for tumor.

Vortex veins negative for tumor.

(See comment)

COMMENT

The tumor in the extraocular space near the conjunctiva is entirely covered by conjunctiva/soft tissue (margins negative). are 1 per 10 high-power fields.

The specimen for part A was sent to the scan documents of

for further diagnostic testing by

which will be reported separately w

GROSS DESCRIPTION

(A) RIGHT EYE, FOR SEND OUT TESTING--pale-gray semitransparent tissue (0.4 x 0.4 x 0.2 cm) within pink-red fluid (0.5 x 0.5 cm) in a sealed container. The specimen is forwarded for send out testing.

(B) RIGHT GLOBE - An enucleation specimen consisting of an intact left lobe (21.0 x 20.0 x 21.0 mm) with an attached 13. optic nerve. The cornea is 11.0 x 10.0 mm with a round central 2.0 mm pupil. The iris is pale gray-yellow with possible rim c hyperpigmentation over approximately one-third peripherally. 1.0 mm from the limbus and adjacent to the area of possible pigmentation, a black 2.0 mm probable tumor nodule is present on the external surface of the sclera with loosely adherent conjunctiva covering the entire surface coming to less than 1.0 mm from the resection edge.

An irregular intraocular multinodular mass with a base approximately 18.0 mm in greatest dimension extends from t and comes to 5.0 mm from the optic nerve within the choroidal space. The mass is located between 2.0 and 6 o'clock. Tum harvested fresh per protocol. The tumor has a maximum height post harvest 4.0 mm and the tumor surface is binodular. A suggested from the external surface, the region of extraocular extension noted on the sclera covered by cornea is visible ad to the tumor. The tumor flattens and becomes thickened again in kind of a rolling/ binodular pattern. An artificial lens is in p

SECTION CODE: B1, regions of vortex veins; B2, optic-nerve margin; B3, B4, calottes with tumor (B3 with extraoc extension and in extraocular tissue harvest); B5, pupil-optic section with tumor.

BIOMARKER TESTING

Primary tumor B5

CLINICAL HISTORY

Right eye uveal melanoma

SNOMED CODES

T-AA000, M-87203

[page 2 of 2]
---END OF REPORT---

Index	Yes	No
1. Name of the person		☒
2. Date of birth		☒
3. Date of death		☒
4. Date of burial		☒
5. Date of cremation		☒
6. Date of interment		☒
7. Date of exhumation		☒
8. Date of reinterment		☒
9. Date of other		☒
10. Date of other		☒
11. Date of other		☒
12. Date of other		☒
13. Date of other		☒
14. Date of other		☒
15. Date of other		☒
16. Date of other		☒
17. Date of other		☒
18. Date of other		☒
19. Date of other		☒
20. Date of other		☒
21. Date of other		☒
22. Date of other		☒
23. Date of other		☒
24. Date of other		☒
25. Date of other		☒
26. Date of other		☒
27. Date of other		☒
28. Date of other		☒
29. Date of other		☒
30. Date of other		☒
31. Date of other		☒
32. Date of other		☒
33. Date of other		☒
34. Date of other		☒
35. Date of other		☒
36. Date of other		☒
37. Date of other		☒
38. Date of other		☒
39. Date of other		☒
40. Date of other		☒
41. Date of other		☒
42. Date of other		☒
43. Date of other		☒
44. Date of other		☒
45. Date of other		☒
46. Date of other		☒
47. Date of other		☒
48. Date of other		☒
49. Date of other		☒
50. Date of other		☒
51. Date of other		☒
52. Date of other		☒
53. Date of other		☒
54. Date of other		☒
55. Date of other		☒
56. Date of other		☒
57. Date of other		☒
58. Date of other		☒
59. Date of other		☒
60. Date of other		☒
61. Date of other		☒
62. Date of other		☒
63. Date of other		☒
64. Date of other		☒
65. Date of other		☒
66. Date of other		☒
67. Date of other		☒
68. Date of other		☒
69. Date of other		☒
70. Date of other		☒
71. Date of other		☒
72. Date of other		☒
73. Date of other		☒
74. Date of other		☒
75. Date of other		☒
76. Date of other		☒
77. Date of other		☒
78. Date of other		☒
79. Date of other		☒
80. Date of other		☒
81. Date of other		☒
82. Date of other		☒
83. Date of other		☒
84. Date of other		☒
85. Date of other		☒
86. Date of other		☒
87. Date of other		☒
88. Date of other		☒
89. Date of other		☒
90. Date of other		☒
91. Date of other		☒
92. Date of other		☒
93. Date of other		☒
94. Date of other		☒
95. Date of other		☒
96. Date of other		☒
97. Date of other		☒
98. Date of other		☒
99. Date of other		☒
100. Date of other		☒

Source: NCI Genomic Data Commons file 7f27a0c5-b919-46a2-957f-dd395de32bf6 (TCGA-WC-A883.FDE93561-B0B0-495F-8BBD-932EA3B7D02D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).